Somatic mutation profile of tumor specimen TCGA-CN-4737-01A (aliquot TCGA-CN-4737-01A-01D-1434-08) from TCGA case TCGA-CN-4737, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 20.0 years (7,301 days).
Specimen TCGA-CN-4737-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20dc6f64-7c33-4ff7-8b2f-101688b38cc0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-4737-10A (Blood Derived Normal), aliquot TCGA-CN-4737-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c2d7325-2936-4c5e-85be-68c19f852c4b

The open-access MAF lists 49 somatic variants for this specimen: 35 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 13, Frame Shift Del 3, Intron 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.503A>T p.H168L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV52676197, COSV52682212, COSV52698349, COSV52762255; called by muse, mutect2, varscan2
- ACTRT2 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs770687267, COSV65759501; called by muse, mutect2, varscan2
- ARMC5 | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs759686063, COSV51655615; called by muse, mutect2, varscan2
- B4GALT2 | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100530494; called by muse, varscan2
- BCL11B | c.1787G>A p.G596D (on ENST00000357195 / NM_001282237.2; = p.G525D on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.013); catalogued as COSV100595034; called by muse, mutect2, varscan2
- COL8A2 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1296464225, COSV100290878; called by muse, mutect2, varscan2
- DCAF4L2 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100150367; called by muse, mutect2, varscan2
- DEFB118 | c.78del p.K26Nfs*19 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | catalogued as rs750510475, COSV53620107; called by mutect2, varscan2
- ENPP3 | c.1207G>T p.A403S | Missense Mutation (SNP) | VAF 59/357 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.483); catalogued as COSV62952832; called by muse, mutect2, varscan2
- EXOC2 | c.1540G>A p.V514M | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as COSV100032417; called by muse, mutect2, varscan2
- GC | c.1271A>G p.E424G | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as COSV99909299; called by muse, mutect2, varscan2
- GFPT1 | c.1562G>A p.R521H (on ENST00000357308 / NM_001244710.2; = p.R503H on NM_002056.4) | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV61949897; called by muse, mutect2, varscan2
- GZF1 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100582338; called by muse, mutect2, varscan2
- IGSF8 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as rs1030236172, COSV100081425; called by muse, mutect2, varscan2
- KIF1B | c.2981C>T p.A994V (on ENST00000377086 / NM_001365952.1; = p.A948V on NM_015074.3) | Missense Mutation (SNP) | VAF 76/273 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV99822193; called by muse, mutect2, varscan2
- KIF4B | c.916C>G p.H306D | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV101469144; called by muse, mutect2, varscan2
- LINS1 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781044699, COSV100129855, COSV59079659; called by muse, mutect2, varscan2
- MFSD6L | c.1369G>A p.V457I | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as rs776309544, COSV100266002; called by muse, mutect2, varscan2
- MRGPRX3 | c.316T>C p.Y106H | Missense Mutation (SNP) | VAF 47/292 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV101283464; called by muse, mutect2, varscan2
- MYOM1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55287221; called by muse, mutect2, varscan2
- NELFB | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV100546747; called by muse, mutect2, varscan2
- NIFK | c.815A>T p.E272V | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as rs913903284, COSV99590496; called by muse, mutect2, varscan2
- OTOGL | c.6029C>G p.S2010C (on ENST00000547103; = p.S2001C on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV100086443; called by muse, mutect2, varscan2
- PKHD1 | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 47/270 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100580715, COSV61858989; called by muse, mutect2, varscan2
- RNF216 | c.2366C>T p.P789L (on ENST00000425013 / NM_207116.3; = p.P846L on NM_207111.4) | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774053707, COSV66290678; called by muse, mutect2, varscan2
- SOX5 | c.1890G>T p.K630N | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100505414, COSV58630155; called by muse, mutect2, varscan2
- SYNE1 | c.12346C>A p.Q4116K (on ENST00000367255 / NM_182961.4; = p.Q4045K on NM_033071.3) | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.366); catalogued as COSV54946441; called by muse, mutect2, varscan2
- TAL1 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1204288003, COSV99595805; called by muse, mutect2
- TEP1 | c.2735G>A p.G912E | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99401377, COSV99402587; called by muse, mutect2, varscan2
- TTC25 | c.1847C>T p.S616L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs188595090, COSV101102837; called by muse, mutect2, varscan2
- TTN | c.96904G>T p.E32302* (on ENST00000591111; = p.E24878* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 49/114 reads (43%) | catalogued as COSV100589280; called by muse, mutect2, varscan2
- ZNF676 | c.1829A>T p.Y610F (on ENST00000650058; = p.Y578F on NM_001001411.3) | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as rs756365733, COSV101236071, COSV101236277; called by muse, mutect2, varscan2
- KIF18B | c.379_382del p.G127Sfs*4 | Frame Shift Del (DEL) | VAF 9/67 reads (13%) | called by mutect2, pindel
- SZT2 | c.5967del p.S1989Rfs*57 (on ENST00000634258 / NM_001365999.1; = p.S1932Rfs*57 on NM_015284.4) | Frame Shift Del (DEL) | VAF 16/146 reads (11%) | called by mutect2, varscan2
- ZNF611 | c.1670_1681del p.T557_H560del | In Frame Del (DEL) | VAF 63/454 reads (14%) | called by mutect2, varscan2
- CHD7 | c.6588C>T p.T2196= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs746103884, COSV71116341; called by muse, mutect2, varscan2
- EPHA5 | c.1743G>A p.V581= | Silent (SNP) | VAF 10/135 reads (7%) | called by muse, mutect2
- FAM193A | c.219C>T p.H73= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as COSV100218407; called by muse, mutect2, varscan2
- FAM214B | c.300G>A p.G100= | Silent (SNP) | VAF 23/304 reads (8%) | catalogued as rs1447786410, COSV100521124; called by muse, mutect2
- FAT1 | c.12438C>T p.H4146= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs760747643, COSV101498600; called by muse, mutect2, varscan2
- FGGY | c.1452C>A p.S484= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs114601020, COSV58026973, COSV58046049; called by muse, mutect2, varscan2
- HARBI1 | c.642G>T p.A214= | Silent (SNP) | VAF 40/275 reads (15%) | catalogued as COSV100365416; called by muse, mutect2, varscan2
- NOP2 | c.2169A>T p.T723= (on ENST00000322166 / NM_001258308.2; = p.T719= on NM_006170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 72/575 reads (13%) | catalogued as COSV100350619; called by muse, mutect2, varscan2
- PELI3 | c.1092C>T p.H364= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs765127805, COSV100291659; called by muse, varscan2
- RBAK | c.1651T>C p.L551= | Silent (SNP) | VAF 17/130 reads (13%) | catalogued as rs1363975571, COSV100806529; called by muse, mutect2, varscan2
- SHROOM3 | c.4263G>A p.S1421= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs763429738, COSV56025550; called by muse, mutect2, varscan2
- TXNDC9 | c.180G>A p.Q60= | Silent (SNP) | VAF 44/201 reads (22%) | catalogued as rs775677288, COSV99176733; called by muse, mutect2, varscan2
- ZNF883 | c.1065T>C p.G355= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as rs762656307; called by muse, mutect2, varscan2
- ST3GAL3 | c.254+9919G>A | Intron (SNP) | VAF 7/36 reads (19%) | catalogued as rs111385873; called by muse, mutect2, varscan2
